Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4XB, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4XB-01A (Primary Tumor).

[page 1 of 2]
Procedure
Received
Report S

Final Diagnosis:

A. Brain, left parieto-occipital mass #1, #2 and #3, biopsy, resection and CUSA: Anaplastic astrocytoma (WHO grade III) with unusual morphology. See comment.

Comment: The tumor shows a prominent cortical and subcortical infiltrative component and an unusual leptomeningeal component associated with desmoplasia, scattered eosinophilic granular bodies and chronic inflammation.

Immunohistochemical stains were performed on paraffin-embedded tissue using antibodies to p53, IDH1 (R132H) and Ki67 (MIB-1). p53 is positive in tumor cells. IDH1 (R132H) immunostain is positive in tumor cells consistent with IDH1 mutation. Ki67 (MIB-1) labeling index is moderate. The findings support the above diagnosis.

Results of neurofilament, S-100, GFAP and PAS immunohistochemical stains will be reported in an addendum.

ADDENDA:

Immunohistochemical and special (PAS) stains were performed on paraffin-embedded tissue using antibodies to GFAP, S-100, neurofilament and PAS. GFAP is strongly positive in tumor cells extending into leptomeninges. S-100 protein highlights the presence of marked reactive gliosis. Neurofilament stain is positive in axons. PAS highlights underlying parenchymal architecture, vascular walls and scattered eosinophilic granular bodies in

ALL EMBEDDED

continued next page Page 1 of 3

ICD-0-3

Astrocytoma, anaplastic 9401/3

Site: brain, occipital C71.4

/w
10/24/12

[page 2 of 2]
leptomeningeal component of the tumor.

Preliminary Frozen Section Consultation:

A. Brain, left parieto-occipital mass #1, resection: Diffuse glioma. Hold over for final type and grade.

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "left parieto-occipital brain mass" are two 3.8 x 3.6 x 0.9 cm and 1.2 x 1.2 x 0.4 cm portions of brain weighing 12.1 grams. There is an ill-defined mass effacing the cortex, approximately 1.1 x 1.0 x 0.9 cm. Smears prepared. Representative sections are submitted. Grossed by

B. Received fresh labeled "left parieto-occipital brain mass #2" are 2 fragments of brain tissue resections measuring 2.0 x 1.1 x 0.5 cm and 2.0 x 1.2 x 0.5 cm. All submitted for permanent sections only. Grossed by

C. Received fresh within a CUSA trap labeled "CUSA trap contents (left parieto-occipital brain mass)" is a 5.0 x 3.8 x 1.2 cm aggregate of gray and white matter. Representative sections are submitted for permanent sections only. Grossed by

Block Summary:

Part A: Left parieto-occipital brain mass

- 1 Lt parieto-occipital mass 1
- 2 Lt parieto-occipital mass 2
- 3 Lt parieto-occipital mass 3
- 4 Lt parieto-occipital mass 4
- 5 Lt parieto-occipital mass 5
- 6 Lt parieto-occipital mass 6
- 7 Lt parieto-occipital mass 7
- 8 Lt parieto-occipital mass 8
- 9 Lt parieto-occipital mass 9

Part B: Left parieto-occipital brain mass #2

- 1 Lt parieto-occipital #2-1
- 2 Lt parieto-occipital #2-2

Part C: CUSA trap contents (left parieto-occipital brain mass)

- 1 Lt parieto-occipital 1
- 2 Lt parieto-occipital 2

ALL EMBEDDED

continued next page Page 2 of 3

10/24/12

Source: NCI Genomic Data Commons file b6f8055a-5cf7-4dd6-9b24-d21e5f54e712 (TCGA-DB-A4XB.EAFB98CA-3206-4193-9FA9-3ECDC5B3A388.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).